Gene-level copy-number profile of tumor specimen HCM-BROD-0648-C71-02A from HCMI case HCM-BROD-0648-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.7 years (23,260 days).
Specimen HCM-BROD-0648-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67760d2f-d5d3-4542-abac-195451f2f298.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0648-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/b7481dad-257a-4a8d-8de0-7c7c457d878d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 4,582; copy number 2: 52,275; copy number 3: 1,714; copy number 4: 14; copy number 5: 99; copy number 6: 84; copy number 7: 7; copy number 16: 11.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–1,011,799, 26 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29.
- chr9:20,341,669–24,592,104, 79 genes (within-gene range 0–3) (broad region; genes not listed).
- chr9:64,462,819–64,498,745, 6 genes: CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.
- chr21:8,986,999–9,129,752, 8 genes: MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 201 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,218,853–204,562,521, 11 genes, copy number 16: PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr7:54,656,358–54,656,734, 1 gene, copy number 6: RPL31P35.
- chr7:54,933,699–55,344,958, 7 genes, copy number 7: AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1.
- chr9:29,254,075–29,318,952, 2 genes, copy number 5: AL162388.1, AL353684.1.
- chr9:32,629,454–36,487,548, 180 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
